Somatic mutation profile of tumor specimen TCGA-EE-A29S-06A (aliquot TCGA-EE-A29S-06A-11D-A197-08) from TCGA case TCGA-EE-A29S, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 83.5 years (30,484 days).
Specimen TCGA-EE-A29S-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22942a09-c63f-4c14-a673-c094875ed040.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29S-10A (Blood Derived Normal), aliquot TCGA-EE-A29S-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9493e67d-2e11-4cf5-86b4-867dcc1331d6

The open-access MAF lists 1,272 somatic variants for this specimen: 810 protein-altering or splice-affecting, 421 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 728, Silent 421, Nonsense Mutation 49, Intron 26, Splice Site 15, Splice Region 13, RNA 8, 3'Flank 3, 5'UTR 3, Translation Start Site 2, Frame Shift Ins 2, In Frame Del 1.

Variants (750 of 1,272; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL7R | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs104893894, CM002997, COSV57411685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 64/177 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADAC | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV51761604; called by muse, mutect2, varscan2
- ABCA10 | c.4103C>T p.T1368I | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV99289515; called by muse, mutect2, varscan2
- ABCA12 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs753119888, COSV55959745; called by muse, mutect2, varscan2
- ABCA3 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs148726153; called by muse, mutect2, varscan2
- ABCA6 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52645656; called by muse, mutect2, varscan2
- ABCA8 | c.2204A>G p.N735S | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV52213190; called by muse, mutect2, varscan2
- ABCC8 | c.2446C>T p.H816Y | Missense Mutation (SNP) | VAF 150/517 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.216); catalogued as COSV56858447; called by muse, mutect2, varscan2
- ABCC9 | c.3283C>T p.R1095C | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752450127, COSV53971662, COSV53981868; called by muse, mutect2, varscan2
- ACAD11 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs561289192, COSV53898061; called by muse, mutect2, varscan2
- ACSF3 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs756279730, COSV100441357, COSV58077846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTC1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV51761829; called by muse, mutect2, varscan2
- ACTG1 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59509891; called by muse, mutect2, varscan2
- ADAM18 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.01); catalogued as COSV55856065, COSV99695279; called by muse, mutect2, varscan2
- ADAM18 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV55844500; called by muse, mutect2, varscan2
- ADAM2 | c.1676G>A p.R559K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55869027; called by muse, mutect2, varscan2
- ADAM28 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as COSV56106031, COSV99738132; called by muse, mutect2, varscan2
- ADAM7 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs868821595, COSV51536734; called by muse, mutect2, varscan2
- ADAMTS12 | c.3573T>A p.S1191R | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61281460; called by muse, mutect2, varscan2
- ADAMTS15 | c.1542+1G>A p.X514_splice | Splice Site (SNP) | VAF 31/73 reads (42%) | catalogued as COSV54510144; called by muse, mutect2, varscan2
- ADAMTS20 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767096383, COSV67138630; called by muse, varscan2
- ADAMTS5 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs267606087, COSV53176912; called by muse, mutect2, varscan2
- ADAMTS6 | c.2723G>A p.W908* | Nonsense Mutation (SNP) | VAF 40/139 reads (29%) | catalogued as COSV58685393; called by muse, mutect2, varscan2
- ADARB2 | c.2078C>A p.P693H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV67182957; called by mutect2, varscan2
- ADCY6 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV57170849; called by muse, mutect2, varscan2
- ADCY6 | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV57170866; called by muse, mutect2, varscan2
- ADGRB2 | c.3862G>A p.G1288S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs1340900539, COSV99926643; called by muse, mutect2
- ADGRE3 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53729676; called by muse, mutect2, varscan2
- ADGRV1 | c.3521G>A p.G1174E | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776576004, COSV67996312; called by muse, mutect2, varscan2
- ADTRP | c.656G>A p.W219* | Nonsense Mutation (SNP) | VAF 49/253 reads (19%) | catalogued as rs772793711, COSV57646154; called by muse, mutect2, varscan2
- AGXT2 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as COSV51491263; called by muse, mutect2
- AHNAK | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as rs779493173, COSV57232591; called by muse, mutect2, varscan2
- AIF1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV61962611; called by muse, varscan2
- AK5 | c.586G>A p.E196K (on ENST00000354567 / NM_174858.3; = p.E170K on NM_012093.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV58355416; called by muse, mutect2, varscan2
- AKTIP | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 119/403 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50889874; called by muse, mutect2, varscan2
- AL121899.2 | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs750048317, COSV67352501; called by muse, varscan2
- AL645922.1 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 216/434 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs766677286, COSV54962775; called by muse, mutect2, varscan2
- AL645922.1 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 115/465 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54962784; called by muse, mutect2, varscan2
- AL645922.1 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54959939; called by muse, mutect2, varscan2
- AL645922.1 | c.3319C>T p.R1107* | Nonsense Mutation (SNP) | VAF 133/564 reads (24%) | catalogued as rs754972855, COSV64887044; called by muse, mutect2, varscan2
- ALDH1A1 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52789291; called by muse, mutect2, varscan2
- ALK | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1013688370, COSV66562966; called by muse, mutect2, varscan2
- ALMS1 | c.6487G>A p.E2163K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as COSV52523020; called by muse, mutect2, varscan2
- ALOX5 | c.1846C>T p.L616= | Splice Region (SNP) | VAF 22/81 reads (27%) | catalogued as COSV65554776; called by muse, mutect2, varscan2
- ALPI | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55016307; called by muse, mutect2, varscan2
- ALPK2 | c.4841C>T p.P1614L | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as rs762488082, COSV100864943; called by muse, mutect2
- ALPK2 | c.4840C>T p.P1614S | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV100864944; called by muse, mutect2, varscan2
- ALS2CL | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs761995012, COSV100015393; called by muse, mutect2, varscan2
- AMACR | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100163331; called by muse, mutect2, varscan2
- AMER3 | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs762007528, COSV58470624; called by muse, mutect2, varscan2
- AMPD3 | c.1273G>T p.A425S (on ENST00000396553 / NM_001025389.2; = p.A434S on NM_000480.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.149); catalogued as rs772010345, COSV101158299; called by muse, mutect2, varscan2
- AMPD3 | c.1274C>T p.A425V (on ENST00000396553 / NM_001025389.2; = p.A434V on NM_000480.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.177); catalogued as COSV101158300; called by muse, mutect2, varscan2
- AMPD3 | c.1517A>G p.N506S (on ENST00000396553 / NM_001025389.2; = p.N515S on NM_000480.3) | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1413306389, COSV67332708; called by muse, mutect2, varscan2
- ANGPT1 | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52458391; called by muse, mutect2, varscan2
- ANGPT1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs868669098, COSV52433932; called by mutect2, varscan2
- ANGPT2 | c.1037T>G p.F346C | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314963219, COSV57340720; called by muse, mutect2, varscan2
- ANKEF1 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65693884; called by muse, mutect2, varscan2
- ANKRD45 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV60962123; called by muse, mutect2, varscan2
- ANO4 | c.1702-1G>A p.X568_splice (on ENST00000392977 / NM_001286615.2; = p.X533_splice on NM_178826.4) | Splice Site (SNP) | VAF 23/43 reads (53%) | catalogued as COSV54615252; called by muse, mutect2, varscan2
- AP5B1 | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100376195; called by muse, mutect2, varscan2
- APBA2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV68788868; called by muse, mutect2, varscan2
- APBA3 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99516582; called by muse, mutect2, varscan2
- APOBEC3C | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1480930677, COSV53329003; called by muse, varscan2
- AREG | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV52644463; called by muse, mutect2, varscan2
- ARHGAP22 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1266607855, COSV99986265; called by muse, mutect2, varscan2
- ARHGAP24 | c.1172C>T p.S391F (on ENST00000395184 / NM_001025616.3; = p.S298F on NM_031305.3) | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV51994106; called by muse, mutect2, varscan2
- ARHGAP39 | c.2914G>A p.E972K (on ENST00000276826 / NM_001308208.2; = p.E1003K on NM_025251.2) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV52776146; called by muse, mutect2, varscan2
- ARID2 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV57595668; called by muse, mutect2, varscan2
- ARNT | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV62232475; called by muse, mutect2, varscan2
- ARPP21 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51809291; called by muse, mutect2, varscan2
- ARRB1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs371702166; called by muse, mutect2, varscan2
- ASTN1 | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as rs201898410, COSV62492108, COSV62507875; called by muse, mutect2, varscan2
- ASXL3 | c.4400G>A p.R1467Q | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs754700314, COSV52462808; called by muse, mutect2, varscan2
- ATP11C | c.1571G>C p.R524T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV59570422; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52878313; called by muse, mutect2, varscan2
- ATP8B4 | c.3409G>A p.G1137S | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52725365; called by muse, mutect2, varscan2
- ATP8B4 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs569305697, COSV52725371; called by muse, mutect2, varscan2
- ATRNL1 | c.4052C>T p.S1351L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV58117165; called by muse, varscan2
- BCR | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); catalogued as rs201471497, COSV59936217; called by muse, mutect2, varscan2
- BGN | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1418964197, COSV59036177; called by muse, mutect2, varscan2
- BMP3 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs866813886, COSV51081796; called by muse, mutect2, varscan2
- BMPER | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV51832439; called by muse, mutect2, varscan2
- BOLL | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as COSV56573458; called by muse, mutect2, varscan2
- BRINP2 | c.2034G>A p.M678I | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs149846085, COSV64178906; called by muse, mutect2, varscan2
- BRINP3 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs868132084, COSV66514748, COSV66523525, COSV66543301; called by muse, varscan2
- BRSK2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57549692; called by muse, mutect2, varscan2
- BTG1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV99755812; called by muse, mutect2, varscan2
- BTG1 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99755815; called by muse, mutect2, varscan2
- C10orf71 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs1454645419, COSV60513953; called by muse, mutect2
- C3 | c.2803G>A p.G935R | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55582165; called by muse, mutect2, varscan2
- C7 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57481847; called by muse, mutect2
- CACNA1E | c.3958G>A p.D1320N | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62429722; called by muse, mutect2, varscan2
- CACNA1E | c.4114G>A p.E1372K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62429735; called by muse, mutect2, varscan2
- CACNA1E | c.5089G>A p.D1697N | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs768500940, COSV62387967, COSV62424409; called by muse, mutect2, varscan2
- CACNA1F | c.4008G>A p.M1336I | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59907208; called by muse, mutect2
- CACNA2D1 | c.2369C>T p.S790L (on ENST00000356253 / NM_001366867.1; = p.S778L on NM_000722.4) | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as rs202108848, COSV62373773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D3 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs761198215, COSV99878233; called by muse, mutect2, varscan2
- CAGE1 | c.1426G>A p.E476K (on ENST00000512086; = p.E340K on NM_205864.3) | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs866412142, COSV57074675; called by muse, mutect2, varscan2
- CALCA | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59028828; called by muse, mutect2, varscan2
- CASP14 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as COSV55664830; called by muse, mutect2, varscan2
- CATSPERB | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56421924; called by muse, mutect2, varscan2
- CBX7 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV53360037; called by muse, mutect2, varscan2
- CCDC141 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs183079562; called by muse, mutect2, varscan2
- CCDC181 | c.1450G>A p.A484T (on ENST00000367806 / NM_001300969.1; = p.A483T on NM_021179.2) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61395021; called by muse, mutect2, varscan2
- CCDC42 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53449909; called by muse, mutect2, varscan2
- CCDC63 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 50/110 reads (45%) | catalogued as rs745666176, COSV57531495; called by muse, mutect2, varscan2
- CCDC74A | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54606747; called by muse, varscan2
- CD14 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV57371519; called by muse, mutect2, varscan2
- CD163 | c.2708G>A p.W903* | Nonsense Mutation (SNP) | VAF 39/119 reads (33%) | catalogued as COSV63129098; called by muse, varscan2
- CD163 | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.091); catalogued as COSV63137847; called by muse, varscan2
- CD163L1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100550837; called by muse, mutect2, varscan2
- CD19 | c.870G>A p.W290* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV61189817; called by muse, mutect2, varscan2
- CD1B | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 108/420 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV63805291; called by muse, mutect2, varscan2
- CD86 | c.445G>A p.E149K (on ENST00000330540 / NM_175862.5; = p.E143K on NM_006889.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.372); catalogued as rs768577906, COSV52610049, COSV52610648; called by muse, mutect2, varscan2
- CD96 | c.985G>A p.G329R (on ENST00000283285 / NM_198196.3; = p.G313R on NM_005816.5) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV51923715; called by muse, mutect2, varscan2
- CDC14A | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as rs1265252432, COSV60563960; called by muse, mutect2, varscan2
- CDH8 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54889201, COSV54903530; called by muse, mutect2, varscan2
- CDK10 | c.962C>T p.S321F (on ENST00000353379 / NM_052988.5; = p.S250F on NM_052987.4) | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs761632963, COSV57048966; called by muse, mutect2, varscan2
- CEP290 | c.4445A>G p.K1482R | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV58356869; called by muse, mutect2, varscan2
- CES5A | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV51871134; called by mutect2, varscan2
- CES5A | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs183957283, COSV51871151; called by muse, mutect2
- CFAP54 | c.8018C>T p.S2673L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs771701442, COSV61572169, COSV61572440; called by muse, mutect2, varscan2
- CFAP58 | c.2063G>A p.R688K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs919306689, COSV63836654; called by muse, mutect2, varscan2
- CFAP58 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.068); catalogued as COSV100866223; called by muse, mutect2, varscan2
- CFAP77 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV58009404; called by muse, varscan2
- CFH | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV62778942; called by muse, mutect2, varscan2
- CFH | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66414166; called by muse, mutect2, varscan2
- CFTR | c.244A>T p.M82L | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CM067768, COSV50111069; called by muse, mutect2, varscan2
- CHRNA3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs759225098, COSV58775073; called by muse, mutect2, varscan2
- CHRNA7 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60976778; called by muse, mutect2, varscan2
- CHRNG | c.1383G>A p.G461= | Splice Region (SNP) | VAF 10/31 reads (32%) | catalogued as COSV51473541; called by muse, mutect2, varscan2
- CIITA | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs751075993, COSV100162636; called by muse, varscan2
- CLEC17A | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as COSV60428218; called by muse, mutect2, varscan2
- CLEC18B | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV60579052; called by muse, mutect2, varscan2
- CLEC5A | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.221); catalogued as COSV69396948; called by muse, mutect2, varscan2
- CLEC7A | c.493-1G>A p.X165_splice (on ENST00000304084 / NM_197947.3; = p.X119_splice on NM_022570.5) | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV53724045; called by muse, mutect2, varscan2
- CMYA5 | c.4621G>A p.E1541K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1219659891, COSV71405609, COSV71409875; called by muse, mutect2, varscan2
- CNOT4 | c.2018C>T p.P673L (on ENST00000541284 / NM_001190850.1; = p.P599L on NM_013316.4) | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as COSV64160607; called by muse, mutect2, varscan2
- CNTN5 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV54346954, COSV54361372; called by muse, mutect2, varscan2
- CNTN5 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164849935, COSV54361388; called by muse, mutect2, varscan2
- CNTNAP2 | c.2794G>A p.G932S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375721802; called by muse, mutect2, varscan2
- CNTNAP2 | c.3047G>T p.R1016L | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV62265209; called by muse, varscan2
- COG5 | c.2086C>T p.R696W (on ENST00000347053 / NM_001379512.1; = p.R717W on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs939793014, COSV51757728, COSV51765618; called by muse, mutect2, varscan2
- COL11A2 | c.4429-1G>A p.X1477_splice (on ENST00000341947 / NM_080680.3; = p.X1370_splice on NM_080679.2) | Splice Site (SNP) | VAF 10/78 reads (13%) | catalogued as COSV59503171; called by muse, mutect2
- COL1A2 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV51966868; called by muse, mutect2, varscan2
- COL27A1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs926781124, COSV61931153; called by muse, mutect2, varscan2
- COL4A1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1382665640, COSV65432611; called by muse, varscan2
- COL4A4 | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV61637113; called by muse, mutect2, varscan2
- COL4A5 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT tolerated (0.64); PolyPhen benign (0.112); catalogued as COSV60373053; called by muse, mutect2, varscan2
- COL4A6 | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57879537; called by muse, mutect2, varscan2
- COL5A3 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53420120; called by muse, mutect2, varscan2
- COL7A1 | c.7144C>T p.P2382S | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV60403835; called by muse, mutect2, varscan2
- COLEC12 | c.166A>C p.I56L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV68374281; called by muse, mutect2, varscan2
- CORIN | c.2834G>A p.G945E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1256200274, COSV56700346; called by muse, mutect2, varscan2
- CPA6 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV52743711; called by muse, mutect2, varscan2
- CPNE1 | c.176C>T p.S59F (on ENST00000352393; = p.S64F on NM_003915.5) | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV58295422; called by muse, mutect2, varscan2
- CPNE4 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.251); catalogued as COSV70198672; called by muse, mutect2, varscan2
- CPS1 | c.3904C>T p.P1302S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV51803179; called by muse, mutect2, varscan2
- CRB1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.432); catalogued as COSV66334283; called by muse, mutect2, varscan2
- CRYGS | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV100330100, COSV57192950; called by muse, mutect2, varscan2
- CRYZL1 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV51680087; called by muse, mutect2, varscan2
- CSMD1 | c.8392T>A p.S2798T (on ENST00000520002; = p.S2797T on NM_033225.6) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.629); catalogued as COSV59390081; called by muse, mutect2, varscan2
- CSMD1 | c.6799C>T p.Q2267* (on ENST00000520002; = p.Q2266* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 51/185 reads (28%) | catalogued as COSV59390105; called by muse, mutect2, varscan2
- CSPP1 | c.716C>T p.S239L (on ENST00000676605; = p.S198L on NM_024790.6) | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1420762506, COSV51593265; called by muse, mutect2, varscan2
- CTBS | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1264541632, COSV55364957; called by muse, mutect2, varscan2
- CTSS | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV64567160; called by muse, mutect2, varscan2
- CTTNBP2NL | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV54743301; called by muse, mutect2, varscan2
- CYB5R4 | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV63752476; called by muse, mutect2
- CYP11B2 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV59996110, COSV59998043; called by muse, mutect2, varscan2
- CYP2C19 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs753980288, COSV64906740; called by muse, mutect2, varscan2
- CYP2C19 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs1178615892, COSV64908387; called by muse, varscan2
- CYP2C9 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV53246791, COSV53249993; called by muse, mutect2, varscan2
- CYP3A4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV60504480; called by muse, mutect2, varscan2
- CYP4F11 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV56126416; called by muse, mutect2, varscan2
- CYP4F12 | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as COSV61173844; called by muse, mutect2, varscan2
- CYP4F2 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746422239, COSV55622086; called by mutect2, varscan2
- CYP7B1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV59582903; called by muse, mutect2, varscan2
- CYTH2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as rs763101707, COSV57310727; called by muse, mutect2, varscan2
- CYTIP | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs763995680, COSV51636381; called by muse, mutect2, varscan2
- DAB1 | c.1247C>T p.P416L (on ENST00000371231; = p.P383L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64690599; called by muse, mutect2, varscan2
- DAB1 | c.868G>A p.D290N (on ENST00000371231; = p.D257N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV64698730; called by muse, mutect2, varscan2
- DAB1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.369); catalogued as COSV59731451; called by muse, mutect2, varscan2
- DBF4 | c.1624C>G p.H542D | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV55999245; called by muse, mutect2, varscan2
- DCDC1 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs1424668477, COSV60860270; called by muse, mutect2, varscan2
- DCDC2 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65834084; called by muse, mutect2, varscan2
- DCLK3 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69364890; called by muse, mutect2, varscan2
- DCTN1 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62621616; called by muse, mutect2, varscan2
- DDHD1 | c.1849G>A p.E617K (on ENST00000323669; = p.E814K on NM_030637.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100079281, COSV100080255; called by muse, mutect2
- DDX60L | c.4088G>C p.G1363A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52722942; called by muse, mutect2
- DEAF1 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58609565; called by muse, mutect2, varscan2
- DENND1C | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV67375482; called by muse, mutect2
- DGAT2L6 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60718894; called by muse, mutect2
- DHODH | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1355943409, COSV54663841; called by muse, mutect2, varscan2
- DHRS9 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59141824; called by muse, mutect2, varscan2
- DMC1 | c.660G>A p.L220= | Splice Region (SNP) | VAF 62/199 reads (31%) | catalogued as COSV53261117; called by muse, mutect2, varscan2
- DNAH17 | c.7280C>T p.S2427F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV67761821; called by muse, mutect2, varscan2
- DNAH3 | c.2323C>T p.L775F | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV54555493; called by muse, mutect2, varscan2
- DNAH5 | c.11176C>T p.Q3726* | Nonsense Mutation (SNP) | VAF 27/85 reads (32%) | catalogued as rs867684159, COSV54208224; called by muse, mutect2, varscan2
- DNAH5 | c.8551G>A p.V2851I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs1412381300, COSV54254977; called by muse, mutect2, varscan2
- DNAH5 | c.8020G>A p.E2674K | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868830185, COSV54238491; called by muse, mutect2, varscan2
- DNAH7 | c.9980C>T p.S3327F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748580627, COSV56788832; called by muse, mutect2, varscan2
- DNAH8 | c.2267G>A p.W756* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100547482; called by muse, mutect2, varscan2
- DNAH8 | c.2268G>C p.W756C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100547483; called by muse, mutect2, varscan2
- DNAH8 | c.10178C>T p.S3393F | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59472862; called by muse, mutect2, varscan2
- DNAH9 | c.7234C>T p.P2412S | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52350008; called by muse, mutect2, varscan2
- DNAH9 | c.7792G>A p.G2598S | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52378877; called by muse, varscan2
- DNAJB14 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62036728; called by muse, mutect2, varscan2
- DPEP3 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs150317704, COSV52053032; called by muse, mutect2, varscan2
- DPP10 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59733520; called by muse, mutect2, varscan2
- DPPA2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.04); catalogued as rs1209157043, COSV72118351; called by muse, mutect2, varscan2
- DPT | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV63191267; called by muse, mutect2, varscan2
- DSC2 | c.2312C>T p.T771I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV51869922; called by muse, mutect2, varscan2
- DSCAM | c.3706G>A p.E1236K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as rs1471305566, COSV68022769; called by muse, varscan2
- DSPP | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.472); catalogued as rs1389022544, COSV56810609, COSV56817115; called by mutect2, varscan2
- DST | c.5160A>T p.L1720F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV99761112; called by muse, mutect2, varscan2
- DTL | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65343313; called by muse, mutect2, varscan2
- DYNAP | c.48G>A p.W16* (on ENST00000321600; = p.W19* on NM_001307955.1) | Nonsense Mutation (SNP) | VAF 41/125 reads (33%) | catalogued as COSV58667361; called by muse, mutect2, varscan2
- DYNC1H1 | c.8548A>G p.I2850V | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.038); catalogued as COSV64143338; called by muse, mutect2, varscan2
- DYNC2H1 | c.6153G>T p.W2051C | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100520050; called by muse, varscan2
- EBF1 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.296); catalogued as rs1215590199, COSV58167520; called by muse, varscan2
- EBF3 | c.1114G>A p.E372K (on ENST00000355311 / NM_001375392.1; = p.E363K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1239465330, COSV62479034, COSV62482428; called by muse, mutect2, varscan2
- EEF1A2 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV53208497; called by muse, mutect2, varscan2
- EEF2KMT | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 65/182 reads (36%) | catalogued as COSV52159666; called by muse, varscan2
- EGFR | c.2947G>A p.G983R | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.375); catalogued as COSV51772666; called by muse, mutect2, varscan2
- EHD1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV57736981; called by muse, mutect2, varscan2
- EIF2B5 | c.1724A>T p.E575V (on ENST00000647909; = p.E567V on NM_003907.3) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56606370; called by muse, mutect2, varscan2
- EIF2D | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV55115742; called by muse, mutect2, varscan2
- EIF3A | c.3525A>G p.P1175= | Splice Region (SNP) | VAF 18/74 reads (24%) | catalogued as COSV64963661; called by muse, mutect2, varscan2
- EIF4A1 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs985461314, COSV99549326; called by muse, mutect2, varscan2
- ELAPOR2 | c.2263G>A p.A755T (on ENST00000450689 / NM_001142749.3; = p.A588T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV51892309; called by muse, mutect2, varscan2
- ELF3 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV62837797; called by muse, mutect2, varscan2
- ENKD1 | c.106A>C p.N36H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV54677848; called by muse, mutect2, varscan2
- ENPEP | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54458071; called by muse, mutect2, varscan2
- ENPP4 | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58090265; called by muse, mutect2, varscan2
- ENPP5 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV57910149; called by muse, mutect2, varscan2
- EPB41L3 | c.2121+2T>C p.X707_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as rs1331828606, COSV59469296; called by muse, mutect2, varscan2
- ERGIC3 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54141087; called by muse, mutect2, varscan2
- ERV3-1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1407305847, COSV51430144; called by muse, mutect2, varscan2
- ETFBKMT | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as COSV63189725; called by muse, mutect2, varscan2
- EVPL | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV101440990; called by muse, mutect2, varscan2
- EYA2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.189); catalogued as COSV57951309; called by muse, varscan2
- F2 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as rs911662015, COSV61317888; called by muse, mutect2, varscan2
- FAM126B | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53775401; called by muse, mutect2, varscan2
- FAM133A | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV59077874; called by muse, mutect2, varscan2
- FAM136A | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs1390587331, COSV50683269; called by muse, mutect2, varscan2
- FAM81B | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV51987249; called by muse, mutect2, varscan2
- FAP | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 44/129 reads (34%) | catalogued as COSV99502649; called by muse, mutect2, varscan2
- FAS | c.582T>A p.N194K (on ENST00000355740 / NM_001320619.2; = p.I222K on NM_000043.6) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious, low confidence (0.05); catalogued as COSV58240233; called by muse, mutect2, varscan2
- FBXL13 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs990857489, COSV57545128; called by muse, mutect2, varscan2
- FEZF2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1285466992, COSV51864698; called by muse, mutect2, varscan2
- FGA | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV57400828; called by muse, mutect2, varscan2
- FGFR1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.114); catalogued as COSV58345274; called by muse, mutect2
- FGFR2 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60658850; called by muse, mutect2, varscan2
- FGFR2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV60643607; called by mutect2, varscan2
- FKBP11 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1381033136, COSV56740401; called by muse, mutect2, varscan2
- FLG2 | c.4643G>A p.G1548E | Missense Mutation (SNP) | VAF 92/366 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.067); catalogued as COSV66168905; called by muse, mutect2, varscan2
- FLG2 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs772554149, COSV66173929, COSV66174478; called by muse, mutect2, varscan2
- FLNB | c.7264G>A p.E2422K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1192269799, COSV55897282; called by muse, mutect2, varscan2
- FLNC | c.5419G>A p.G1807R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57965943; called by muse, mutect2
- FLRT2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV58151030; called by muse, mutect2, varscan2
- FLT3 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54072157; called by muse, mutect2, varscan2
- FLT4 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as rs781305649, COSV56123953; called by muse, mutect2, varscan2
- FN1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1018955766, COSV60546039; called by muse, mutect2, varscan2
- FNBP1L | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.945); catalogued as COSV53094559, COSV53096913; called by muse, mutect2, varscan2
- FRAS1 | c.7811C>T p.S2604F | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs1165209958, COSV53652438; called by muse, mutect2, varscan2
- FREM1 | c.2368G>A p.G790R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764691131, COSV66530883; called by muse, varscan2
- FRMD3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV100419278; called by muse, mutect2, varscan2
- FRMPD2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV59724260; called by muse, mutect2, varscan2
- FSTL5 | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.817); catalogued as COSV60233547; called by muse, mutect2, varscan2
- FYB2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV58589718; called by muse, mutect2
- FZD7 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV99637536; called by mutect2, varscan2
- FZD7 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99637539; called by muse, mutect2, varscan2
- GABRA3 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 76/115 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64805915; called by muse, varscan2
- GABRG1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54962532; called by muse, mutect2, varscan2
- GABRG1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV54962539; called by muse, mutect2, varscan2
- GABRR3 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760476762, COSV72084269; called by muse, mutect2, varscan2
- GAD1 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as rs111361241, COSV60154371; called by muse, mutect2, varscan2
- GAL3ST4 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200159207, COSV100385513; called by muse, mutect2, varscan2
- GALNTL5 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs926094593, COSV67179699; called by muse, mutect2, varscan2
- GDF5 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371529960; called by mutect2, varscan2
- GK5 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.475); catalogued as COSV67486931; called by muse, mutect2, varscan2
- GLI2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58052210; called by muse, mutect2
- GLYAT | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53538375; called by muse, mutect2, varscan2
- GPX5 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69079309; called by muse, mutect2, varscan2
- GRIA2 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs267600059, COSV52381695, COSV99644046; called by muse, mutect2, varscan2
- GRID2 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as COSV56187822, COSV56273645; called by muse, mutect2, varscan2
- GRIN2D | c.3349G>A p.D1117N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs780920585, COSV53520975; called by muse, mutect2, varscan2
- GRM3 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs867538929, COSV64480361; called by muse, mutect2
- GRXCR1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67670829; called by muse, mutect2, varscan2
- GTF3C1 | c.4754G>A p.R1585K | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs748635595, COSV62245300; called by muse, mutect2, varscan2
- GTF3C4 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV64646260; called by muse, mutect2, varscan2
- H2BC6 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 93/192 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs763821729, COSV61591826; called by muse, mutect2, varscan2
- HABP4 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV64515394; called by muse, mutect2, varscan2
- HAPLN1 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57149974, COSV57152357; called by muse, mutect2, varscan2
- HAUS3 | c.761T>G p.I254S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV71319300; called by muse, mutect2, varscan2
- HBG1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.851); catalogued as COSV100400730, COSV57963403; called by mutect2, varscan2
- HBG2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.851); catalogued as COSV57962999; called by muse, mutect2, varscan2
- HCFC1 | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100130204; called by muse, mutect2, varscan2
- HECW1 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1371735445, COSV67840971; called by muse, mutect2, varscan2
- HECW2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53668403; called by muse, mutect2, varscan2
- HFM1 | c.2153G>A p.W718* | Nonsense Mutation (SNP) | VAF 38/116 reads (33%) | catalogued as COSV54038209; called by muse, mutect2, varscan2
- HKDC1 | c.2372G>A p.S791N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1160171284, COSV63579677; called by muse, mutect2, varscan2
- HMCN1 | c.833T>C p.L278S | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54945262; called by muse, mutect2, varscan2
- HMGCS2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 172/542 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65569467; called by muse, mutect2, varscan2
- HNF1B | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 174/572 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs377555356; called by muse, mutect2, varscan2
- HOXA3 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.195); catalogued as rs1010368098, COSV57829173, COSV57829325; called by muse, mutect2
- HR | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs769152937, COSV57194919; called by muse, mutect2, varscan2
- HRNR | c.2060G>A p.S687N | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs763924232, COSV64263337; called by muse, mutect2, varscan2
- HRNR | c.1793G>A p.G598D | Missense Mutation (SNP) | VAF 125/511 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV64263342; called by muse, mutect2, varscan2
- HSPA1L | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 242/907 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65151334; called by muse, mutect2, varscan2
- HTR5A | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.257); catalogued as COSV55287627; called by muse, mutect2, varscan2
- HTR5A | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756258628, COSV55287643, COSV99839555; called by muse, mutect2, varscan2
- HYDIN | c.6394G>A p.E2132K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as rs373417090; called by muse, mutect2, varscan2
- HYDIN | c.5938G>A p.E1980K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.263); catalogued as rs1167081936, COSV59253467; called by mutect2, varscan2
- IFNB1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV66525109; called by muse, mutect2, varscan2
- IGSF5 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV66029743; called by muse, mutect2, varscan2
- IKBKE | c.1353G>C p.Q451H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV65627168; called by muse, mutect2, varscan2
- IL21R | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as COSV61970558; called by muse, mutect2, varscan2
- IL6R | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV59819736; called by muse, mutect2
- IL7 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV55678428; called by muse, mutect2, varscan2
- IMPG1 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100886732, COSV64062317; called by muse, mutect2, varscan2
- INTS13 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV53905770; called by muse, mutect2, varscan2
- IPO11 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV57583436; called by muse, mutect2, varscan2
- IQSEC2 | c.3128G>A p.G1043E (on ENST00000642864 / NM_001111125.3; = p.G838E on NM_015075.2) | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100945003, COSV64728310; called by muse, mutect2, varscan2
- IRX6 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs1049450659, COSV51862456; called by muse, mutect2, varscan2
- ITGB8 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV56014865; called by muse, mutect2, varscan2
- ITIH5 | c.965T>G p.L322R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53674930; called by muse, mutect2, varscan2
- KASH5 | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV71357903; called by muse, varscan2
- KCNA6 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV54978252; called by muse, mutect2
- KCNAB1 | c.293G>A p.G98E (on ENST00000490337 / NM_172160.3; = p.G87E on NM_003471.3) | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779267601, COSV56755086; called by muse, mutect2, varscan2
- KCNB1 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65571072; called by muse, mutect2, varscan2
- KCNB2 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs1196389232, COSV73053196; called by muse, mutect2, varscan2
- KCNH7 | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59815118; called by muse, mutect2, varscan2
- KCNJ1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV60662918; called by muse, mutect2, varscan2
- KCNQ3 | c.1236G>A p.R412= | Splice Region (SNP) | VAF 55/94 reads (59%) | catalogued as COSV66482979; called by muse, mutect2, varscan2
- KCNQ5 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59667280, COSV59677991; called by muse, mutect2, varscan2
- KCNT2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV54111446; called by muse, mutect2, varscan2
- KHDRBS2 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs763209117, COSV55495046, COSV99838541; called by muse, mutect2, varscan2
- KIAA0319 | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as COSV65502184; called by muse, mutect2, varscan2
- KIAA1109 | c.9256G>A p.G3086R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52694921; called by muse, mutect2, varscan2
- KIAA1217 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV56824686; called by muse, mutect2, varscan2
- KIF21A | c.2123C>T p.S708F (on ENST00000361418 / NM_001378440.1; = p.S695F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV62778638; called by muse, mutect2, varscan2
- KIF21B | c.4513G>A p.D1505N (on ENST00000422435 / NM_001252100.2; = p.D1492N on NM_017596.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs144049379; called by muse, varscan2
- KIF5B | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV56656547; called by muse, mutect2, varscan2
- KIFC1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750141338, COSV65737431; called by muse, mutect2
- KLHL14 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100809383; called by muse, varscan2
- KRT1 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV52869559; called by muse, mutect2, varscan2
- KRT10 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.08); catalogued as rs991121036, COSV54089334, COSV54091668; called by muse, mutect2, varscan2
- KRT19 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1470431614, COSV54182252; called by muse, mutect2, varscan2
- KRT38 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99878451; called by muse, varscan2
- KRT38 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs776562651, COSV99878457; called by muse, varscan2
- KRT71 | c.1326G>A p.R442= | Splice Region (SNP) | VAF 29/65 reads (45%) | catalogued as COSV57293273; called by muse, mutect2, varscan2
- KRTAP10-5 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV59954524, COSV59968821; called by muse, mutect2, varscan2
- KRTAP10-7 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.935); catalogued as COSV100170366; called by muse, varscan2
- KRTAP13-3 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV61878969; called by muse, mutect2, varscan2
- LAMA1 | c.7925C>A p.S2642* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV67534774, COSV67544997; called by muse, mutect2, varscan2
- LAMA3 | c.5315G>A p.G1772E (on ENST00000313654 / NM_198129.4; = p.G163E on NM_000227.6) | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD1212972, COSV52544096; called by muse, mutect2, varscan2
- LAMP5 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs372920766; called by muse, mutect2
- LCE2D | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.294); catalogued as COSV100909528, COSV64229271; called by muse, mutect2, varscan2
- LCE3D | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV64231314; called by muse, varscan2
- LCOR | c.4295C>T p.P1432L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1434407066, COSV53718713; called by muse, mutect2, varscan2
- LEPR | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); catalogued as COSV60748665, COSV60764422; called by muse, mutect2, varscan2
- LEPR | c.3194G>A p.G1065E | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV62745991; called by muse, mutect2, varscan2
- LGR4 | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); catalogued as rs961908195, COSV64866473; called by muse, mutect2, varscan2
- LHCGR | c.867-2A>T p.X289_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV54303823; called by muse, mutect2, varscan2
- LHX4 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs1274360714, COSV55373050; called by muse, mutect2, varscan2
- LIPH | c.1012T>G p.W338G | Missense Mutation (SNP) | VAF 169/550 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56186593; called by muse, mutect2, varscan2
- LIPN | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356397112, COSV68384568; called by muse, mutect2, varscan2
- LMO7 | c.2458G>A p.G820R (on ENST00000357063; = p.G501R on NM_005358.5) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs757559296, COSV100413926, COSV58550395; called by muse, mutect2, varscan2
- LOXL2 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763353774, COSV66690379; called by muse, mutect2, varscan2
- LPAR1 | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV62687484; called by muse, mutect2, varscan2
- LRBA | c.5113C>T p.L1705F | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.997); catalogued as COSV63965978; called by muse, mutect2, varscan2
- LRFN5 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs1382368397, COSV53244776; called by muse, mutect2, varscan2
- LRFN5 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV53250796, COSV53268682; called by muse, mutect2, varscan2
- LRIG1 | c.2152G>A p.G718R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490318181, COSV56243123; called by muse, mutect2, varscan2
- LRP1B | c.12871G>A p.D4291N | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV67261164, COSV67279342; called by muse, mutect2, varscan2
- LRP2 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.428); catalogued as COSV55576775; called by muse, mutect2, varscan2
- LRP4 | c.2094G>T p.G698= | Splice Region (SNP) | VAF 32/87 reads (37%) | catalogued as COSV66138619, COSV66138966; called by mutect2, varscan2
- LRRC55 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV73007042; called by muse, mutect2, varscan2
- LRRC7 | c.932G>A p.G311E (on ENST00000651989 / NM_001370785.2; = p.G278E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV50642067; called by muse, mutect2, varscan2
- LSM7 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1472605129, COSV99396010; called by muse, mutect2, varscan2
- LTBP2 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1201854863, COSV56214720; called by muse, mutect2, varscan2
- LUZP4 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 79/115 reads (69%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV64218730; called by muse, mutect2, varscan2
- MAEL | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63112269; called by muse, mutect2, varscan2
- MAN2B1 | c.2524C>T p.H842Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327029675, COSV55475576; called by muse, mutect2, varscan2
- MAP1A | c.7321C>T p.P2441S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV55813426; called by muse, mutect2, varscan2
- MAP3K15 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV58839590; called by muse, mutect2, varscan2
- MAP4K3 | c.1973G>A p.R658K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as COSV55719128; called by muse, mutect2, varscan2
- MAPK10 | c.133G>A p.D45N (on ENST00000359221 / NM_001351625.2; = p.D83N on NM_002753.5) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60395093; called by muse, mutect2, varscan2
- MAPK4 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68544063; called by muse, mutect2, varscan2
- MAPK4 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); catalogued as COSV68544072; called by muse, mutect2, varscan2
- MARCO | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59059187; called by muse, mutect2, varscan2
- MASP1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV51462994, COSV51464230; called by muse, mutect2, varscan2
- MAST4 | c.6340G>A p.D2114N (on ENST00000403625 / NM_001164664.2; = p.D1925N on NM_015183.3) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.069); catalogued as rs866892574, COSV55143867; called by muse, mutect2, varscan2
- MCHR2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs200390537, COSV56009277; called by muse, mutect2, varscan2
- MEI1 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV55908324; called by muse, mutect2, varscan2
- MERTK | c.2891G>A p.R964K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV54936472; called by muse, mutect2, varscan2
- MFNG | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV52660443; called by muse, varscan2
- MFSD6 | c.1530C>T p.I510= | Splice Region (SNP) | VAF 28/87 reads (32%) | catalogued as COSV55625775; called by muse, mutect2, varscan2
- MGLL | c.10G>A p.E4K (on ENST00000398104 / NM_001003794.2; = p.E14K on NM_007283.6) | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs1332459523, COSV54030578; called by muse, mutect2, varscan2
- MIGA1 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV66225143; called by muse, mutect2, varscan2
- MKRN3 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs189798006, COSV58810490, COSV58812431; called by muse, mutect2, varscan2
- MME | c.1309A>G p.K437E | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV64708612; called by muse, mutect2, varscan2
- MMP12 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs868954103, COSV58261759; called by muse, mutect2, varscan2
- MOV10L1 | c.885-1G>A p.X295_splice | Splice Site (SNP) | VAF 24/67 reads (36%) | catalogued as COSV53180395; called by muse, mutect2, varscan2
- MPP6 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.533); catalogued as COSV56041559, COSV56043569; called by muse, mutect2, varscan2
- MROH2B | c.2966C>T p.S989F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV68189996, COSV68190072, COSV68190262; called by muse, varscan2
- MTHFSD | c.676T>C p.F226L (on ENST00000360900 / NM_001159377.2; = p.F225L on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59804940; called by muse, mutect2
- MUC16 | c.20213G>A p.R6738Q | Missense Mutation (SNP) | VAF 189/412 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67474551; called by muse, mutect2, varscan2
- MUC16 | c.18568G>A p.D6190N | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.048); catalogued as COSV67455067, COSV67496912; called by muse, mutect2, varscan2
- MUC16 | c.3655C>T p.P1219S | Missense Mutation (SNP) | VAF 199/412 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); catalogued as rs769830116, COSV67454358; called by muse, mutect2, varscan2
- MUC17 | c.9077C>T p.S3026F | Missense Mutation (SNP) | VAF 137/379 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); catalogued as rs1220192316, COSV60305379; called by muse, mutect2, varscan2
- MUC17 | c.9782C>T p.S3261L | Missense Mutation (SNP) | VAF 113/341 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1354785956, COSV60289436; called by muse, mutect2, varscan2
- MYB | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100215277; called by muse, mutect2, varscan2
- MYCT1 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV65892091; called by muse, mutect2, varscan2
- MYH15 | c.3462C>A p.D1154E | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV56320861; called by muse, mutect2, varscan2
- MYH2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs868304109, COSV55449639; called by muse, mutect2, varscan2
- MYH7 | c.1957-1G>A p.X653_splice | Splice Site (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100806870; called by muse, mutect2, varscan2
- MYLK3 | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471946055, COSV67367102; called by muse, varscan2
- MYO3A | c.4293G>A p.Q1431= | Splice Region (SNP) | VAF 16/56 reads (29%) | catalogued as rs1008902355, COSV56351290; called by muse, mutect2, varscan2
- MYO3B | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762080125, COSV58719127; called by muse, mutect2, varscan2
- MYOM2 | c.2577G>A p.W859* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV50783278; called by muse, mutect2, varscan2
- MYOM2 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs376313294; called by muse, mutect2, varscan2
- MYRIP | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56883218; called by muse, mutect2, varscan2
- NCF2 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV62316854; called by muse, varscan2
- NCL | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV59545809; called by muse, mutect2, varscan2
- NDST4 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV52139137; called by muse, mutect2, varscan2
- NDST4 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52139149; called by muse, mutect2, varscan2
- NEFM | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55335159; called by muse, varscan2
- NELFE | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 151/597 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.079); catalogued as COSV64814508; called by muse, mutect2, varscan2
- NEUROD6 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.506); catalogued as COSV51770847, COSV51773858; called by muse, mutect2, varscan2
- NEXMIF | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV50031628; called by muse, varscan2
- NFAT5 | c.1951T>A p.S651T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as COSV100591375; called by muse, mutect2, varscan2
- NFAT5 | c.1952C>A p.S651* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100591380; called by muse, varscan2
- NFU1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100361408; called by muse, varscan2
- NFXL1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as rs771628302, COSV61200997; called by muse, mutect2, varscan2
- NGDN | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1428112172, COSV68143193; called by muse, mutect2, varscan2
- NGF | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772557857, COSV101049373, COSV65686846; called by muse, mutect2, varscan2
- NIBAN1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100836526, COSV62286515; called by muse, mutect2, varscan2
- NID1 | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV51629583; called by muse, mutect2, varscan2
- NKAIN4 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV53903459; called by muse, mutect2, varscan2
- NKX3-1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV66512743; called by muse, mutect2, varscan2
- NME7 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as rs138530600, COSV63164786; called by muse, mutect2, varscan2
- NMS | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.099); catalogued as rs772642162, COSV65258402; called by muse, mutect2, varscan2
- NOD2 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV56055168; called by muse, mutect2, varscan2
- NOMO1 | c.3272C>T p.S1091F | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1333503865, COSV55061680; called by muse, mutect2, varscan2
- NPAP1 | c.2795C>T p.S932L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV61511830; called by muse, mutect2, varscan2
- NPAS4 | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60650132, COSV60653007; called by muse, mutect2, varscan2
- NPC1 | c.359T>A p.F120Y | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); catalogued as COSV52584092; called by mutect2, varscan2
- NPHS2 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs267598209, COSV62634835; called by muse, mutect2, varscan2
- NR0B2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54260271; called by muse, varscan2
- NR1D2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV100437628; called by muse, mutect2, varscan2
- NRDE2 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs922228851, COSV62964899; called by muse, mutect2, varscan2
- NRP2 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs745533260, COSV55929738, COSV55931644; called by muse, mutect2, varscan2
- NTN3 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53549004; called by muse, mutect2, varscan2
- NUP210L | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55139680; called by muse, mutect2, varscan2
- NVL | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs571963590, COSV55876667; called by muse, mutect2, varscan2
- NYAP1 | c.1776G>C p.E592D | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV55722406; called by muse, varscan2
- NYAP1 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV55722416; called by muse, varscan2
- OBSCN | c.10391G>A p.G3464E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.68); catalogued as COSV52835015; called by muse, mutect2, varscan2
- OLFML2B | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs751871224, COSV54200756; called by muse, mutect2, varscan2
- OR10A6 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs148940548, COSV59165179; called by muse, varscan2
- OR10K2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV59222237; called by muse, mutect2, varscan2
- OR10Z1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 106/394 reads (27%) | catalogued as COSV63525307; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by mutect2, varscan2
- OR11L1 | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV100869521, COSV63315862; called by muse, mutect2, varscan2
- OR12D2 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV65827087, COSV65828278; called by muse, mutect2, varscan2
- OR1A1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58404756; called by muse, mutect2, varscan2
- OR1D2 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58922603; called by muse, mutect2, varscan2
- OR1J4 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV61590415; called by muse, mutect2, varscan2
- OR1N2 | c.502C>G p.R168G | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV65460401, COSV65461286; called by muse, mutect2, varscan2
- OR2A14 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.042); catalogued as COSV68718733; called by muse, mutect2, varscan2
- OR2G2 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60742489; called by mutect2, varscan2
- OR2G2 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.689); catalogued as COSV60742495; called by muse, varscan2
- OR2G2 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.282); catalogued as COSV60740434, COSV60742507; called by muse, varscan2
- OR2G6 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs777352444, COSV58575979; called by muse, mutect2, varscan2
- OR2T8 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs145320774; called by muse, mutect2, varscan2
- OR4C6 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV58602871; called by mutect2, varscan2
- OR4K14 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59294362; called by muse, mutect2, varscan2
- OR4K5 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 26/151 reads (17%) | catalogued as COSV100262114; called by muse, mutect2, varscan2
- OR4N2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60050301; called by muse, mutect2, varscan2
- OR51A7 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as COSV100834787; called by muse, mutect2, varscan2
- OR51E2 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs767765213, COSV67808398; called by muse, mutect2, varscan2
- OR51G2 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.964); catalogued as rs1279856287, COSV58995280; called by muse, mutect2, varscan2
- OR51L1 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58625317, COSV58625919; called by muse, mutect2, varscan2
- OR52A5 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs1370098431, COSV56616967; called by muse, mutect2, varscan2
- OR52J3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs372164802; called by muse, mutect2, varscan2
- OR52N4 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs1416131613, COSV57890953, COSV57893224; called by muse, mutect2, varscan2
- OR56B1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1255409068, COSV57723539; called by muse, mutect2, varscan2
- OR5AK2 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372725475, COSV58805334; called by muse, mutect2, varscan2
- OR5K1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60304057; called by muse, mutect2, varscan2
- OR5K3 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs774041879, COSV67349886; called by muse, mutect2, varscan2
- OR5T2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57591142; called by muse, mutect2, varscan2
- OR6Q1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761582438, COSV56933080; called by muse, mutect2, varscan2
- OR7D2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV60141534; called by muse, mutect2, varscan2
- OSBPL10 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 123/239 reads (51%) | catalogued as COSV67338307; called by muse, mutect2, varscan2
- OTOF | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as COSV55521835; called by muse, mutect2, varscan2
- OTOF | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs138720253; called by muse, mutect2, varscan2
- OTOGL | c.2509C>T p.P837S (on ENST00000547103; = p.P828S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV72007411; called by muse, mutect2, varscan2
- P4HA3 | c.1181G>A p.W394* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV59044213; called by muse, mutect2, varscan2
- PACS2 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs782179266, COSV57652885, COSV57657711; called by muse, mutect2
- PADI3 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.122); catalogued as rs760768287, COSV64935499, COSV64935743; called by muse, mutect2, varscan2
- PADI4 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV64924053; called by muse, mutect2, varscan2
- PAPPA | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs771674986, COSV60292727; called by muse, mutect2, varscan2
- PCBP4 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs767718245, COSV59055966, COSV59056353; called by muse, mutect2, varscan2
- PCDH11Y | c.373C>T p.R125C (on ENST00000400457 / NM_032973.2; = p.R114C on NM_032971.3) | Missense Mutation (SNP) | VAF 75/128 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53081190; called by muse, mutect2, varscan2
- PCDH18 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61272458; called by muse, mutect2, varscan2
- PCDHB15 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as COSV51425856; called by muse, mutect2, varscan2
- PCDHB15 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50859593, COSV51224807, COSV51304473; called by muse, mutect2, varscan2
- PCDHB3 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | catalogued as rs868906699, COSV50637777; called by muse, mutect2, varscan2
- PCDHB4 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554274440, COSV52020064; called by muse, mutect2, varscan2
- PCDHGA6 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as COSV54042519; called by muse, mutect2, varscan2
- PCDHGB4 | c.1092T>G p.I364M | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54042543; called by muse, mutect2, varscan2
- PCNX2 | c.4957G>A p.D1653N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV50910468; called by muse, mutect2, varscan2
- PCNX2 | c.4342G>A p.E1448K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386409105, COSV50790313; called by muse, mutect2, varscan2
- PDCD11 | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV63935538; called by muse, mutect2, varscan2
- PDE1A | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1277731579, COSV100116905; called by muse, mutect2, varscan2
- PDE4DIP | c.6841G>A p.E2281K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as COSV57731244; called by muse, mutect2, varscan2
- PDE6B | c.1972C>T p.H658Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55331255; called by muse, mutect2
- PDZRN3 | c.2156G>A p.W719* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV55216717; called by muse, mutect2, varscan2
- PENK | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59243487; called by muse, mutect2, varscan2
- PHF12 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV52022473; called by muse, mutect2, varscan2
- PI16 | c.61A>C p.T21P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV65448820; called by muse, mutect2, varscan2
- PID1 | c.601G>A p.E201K (on ENST00000354069 / NM_001330156.1; = p.E199K on NM_017933.5) | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.389); catalogued as COSV62475746, COSV62483403; called by muse, mutect2, varscan2
- PIGG | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV56316352; called by mutect2, varscan2
- PIK3C2B | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.28); catalogued as COSV65804271; called by muse, mutect2, varscan2
- PIK3CB | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 191/582 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV56685503; called by muse, mutect2, varscan2
- PIWIL1 | c.1824G>A p.M608I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); catalogued as COSV55352545; called by muse, mutect2, varscan2
- PKD2 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV52941587; called by muse, mutect2, varscan2
- PKHD1L1 | c.5233G>A p.E1745K | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV65754405; called by muse, mutect2, varscan2
- PKHD1L1 | c.8092G>A p.E2698K | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs749031346, COSV101005757, COSV65754413; called by muse, varscan2
- PKHD1L1 | c.8191C>T p.P2731S | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65754421; called by muse, varscan2
- PLA2G4C | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV62788206; called by muse, mutect2, varscan2
- PLCB2 | c.373-1G>A p.X125_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV53038470; called by muse, mutect2, varscan2
- PLCH1 | c.194T>C p.L65P (on ENST00000340059 / NM_001130960.2; = p.L77P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58193733, COSV58210944; called by muse, mutect2, varscan2
- PLCXD3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746073648, COSV60610978, COSV60618210; called by muse, mutect2, varscan2
- PLCZ1 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56859326; called by muse, mutect2, varscan2
- PLCZ1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190644019, COSV56859343; called by muse, mutect2, varscan2
- PLEK2 | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53607057; called by muse, mutect2, varscan2
- PLEKHA6 | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs757765400, COSV55340833; called by muse, mutect2, varscan2
- PLXDC2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as COSV65923701; called by muse, mutect2, varscan2
- PLXDC2 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | catalogued as rs749464992, COSV65900855, COSV65903364; called by muse, mutect2, varscan2
- PNLIP | c.693G>A p.G231= | Splice Region (SNP) | VAF 26/86 reads (30%) | catalogued as rs745641207, COSV65042100; called by muse, mutect2, varscan2
- POF1B | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.608); catalogued as rs1346411016, COSV53141179; called by muse, mutect2, varscan2
- POLA2 | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55484617, COSV99641510; called by muse, mutect2, varscan2
- POLA2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247428141, COSV99641513; called by muse, mutect2, varscan2
- POLQ | c.7143G>T p.Q2381H | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV51762480; called by muse, mutect2, varscan2
- POMGNT1 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 44/130 reads (34%) | PolyPhen probably damaging (0.999); catalogued as COSV64341081; called by muse, mutect2, varscan2
- POTEH | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.555); catalogued as rs760807244, COSV58882143; called by muse, varscan2
- PPEF2 | c.579+1G>A p.X193_splice | Splice Site (SNP) | VAF 25/91 reads (27%) | catalogued as COSV54426826; called by muse, mutect2, varscan2
- PPIB | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.357); catalogued as COSV55521434; called by muse, mutect2, varscan2
- PPP1R16B | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as COSV55378127, COSV55385570; called by muse, mutect2, varscan2
- PPP1R35 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV52770101; called by muse, mutect2, varscan2
- PRAME | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1340569390, COSV67162552; called by muse, mutect2, varscan2
- PRAMEF1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 95/332 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.962); catalogued as COSV60007293; called by muse, mutect2, varscan2
- PRB2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.839); catalogued as COSV66984363; called by mutect2, varscan2
- PREX2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs200600940; called by muse, mutect2, varscan2
- PRICKLE2 | c.264T>G p.C88W (on ENST00000295902; = p.C32W on NM_198859.4) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55772426; called by muse, mutect2, varscan2
- PRKCQ | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as COSV54110785, COSV54120021; called by muse, mutect2, varscan2
- PROM2 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV58301075; called by muse, mutect2, varscan2
- PROP1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1032983024, COSV57645539; called by muse, mutect2, varscan2
- PRRC2A | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV63225074; called by muse, mutect2, varscan2
- PSG11 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV60458222; called by muse, mutect2, varscan2
- PTGIS | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs746476312, COSV54839960; called by muse, mutect2, varscan2
- PTPN14 | c.1664C>G p.T555R | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV65281112, COSV65289088; called by muse, mutect2, varscan2
- PTPN20 | c.281G>A p.W94* | Nonsense Mutation (SNP) | VAF 62/363 reads (17%) | catalogued as rs1555141314; called by muse, mutect2, varscan2
- PTPRB | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.958); catalogued as rs373810196; called by muse, mutect2, varscan2
- PTPRB | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.053); catalogued as COSV51741721; called by muse, mutect2, varscan2
- PTPRD | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61984899; called by muse, mutect2, varscan2
- PTPRF | c.5198C>T p.T1733I | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63449277; called by muse, mutect2, varscan2
- PTPRJ | c.2336A>T p.E779V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV69254894; called by mutect2, varscan2
- PXDN | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs765145239, COSV53227567; called by mutect2, varscan2
- PYGM | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51230021, COSV99377591; called by muse, mutect2, varscan2
- PYHIN1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV63724121; called by muse, mutect2, varscan2
- PYROXD2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV65331569; called by muse, mutect2, varscan2
- RAB11FIP1 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV54764415; called by muse, mutect2, varscan2
- RAG2 | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1306056884, COSV57560018; called by muse, mutect2, varscan2
- RALGAPA1 | c.4714C>T p.Q1572* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV51898097; called by muse, mutect2, varscan2
- RALYL | c.858G>A p.L286= | Splice Region (SNP) | VAF 35/125 reads (28%) | catalogued as COSV72826109; called by muse, mutect2, varscan2
- RASGRF1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs150981409, COSV69179127; called by muse, varscan2
- RASGRF1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV69180077, COSV69183685; called by muse, varscan2
- RBM11 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV68748404; called by muse, varscan2
- RBM25 | c.1144A>C p.S382R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.944); catalogued as COSV56203209; called by muse, mutect2, varscan2
- RBM47 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV55944063; called by muse, mutect2, varscan2
- RBP3 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs868983465; called by muse, varscan2
- RC3H1 | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51220227; called by muse, mutect2, varscan2
- REG3A | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs749016320, COSV59412199, COSV59412447; called by muse, mutect2, varscan2
- REN | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV65818463; called by muse, mutect2, varscan2
- REN | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV99689772; called by muse, mutect2
- RETSAT | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1458746653, COSV55526226, COSV55529190; called by muse, mutect2, varscan2
- RGL2 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.082); catalogued as COSV69916607; called by muse, mutect2, varscan2
- RHBDF1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs746482832, COSV51954367; called by muse, mutect2, varscan2
- RICTOR | c.4382T>A p.F1461Y | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.136); catalogued as COSV99705907; called by muse, mutect2, varscan2
- RICTOR | c.4381T>C p.F1461L | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99705910; called by muse, mutect2, varscan2
- RLN3 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as COSV54603454; called by muse, mutect2, varscan2
- RNF148 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 87/335 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775246153, COSV57388023; called by muse, mutect2, varscan2
- RNF165 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV53971358; called by muse, mutect2, varscan2
- RNF17 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV55052662, COSV55054092; called by muse, mutect2, varscan2
- RNF213 | c.8210C>T p.P2737L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs1473027345, COSV60410002; called by muse, mutect2, varscan2
- RNF40 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs754279522, COSV61216887; called by muse, mutect2, varscan2
- ROBO2 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV100170658, COSV59942234; called by muse, mutect2, varscan2
- RPL27 | c.170T>A p.M57K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV53814530, COSV53815591; called by muse, mutect2, varscan2
- RPTN | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs370006914, COSV60166809; called by muse, mutect2, varscan2
- RSBN1 | c.2039G>C p.R680T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54735658; called by muse, mutect2, varscan2
- RSPH14 | c.792G>A p.G264= | Splice Region (SNP) | VAF 28/101 reads (28%) | catalogued as COSV53267250; called by muse, mutect2, varscan2
- RTKN | c.352C>T p.R118C (on ENST00000272430 / NM_001015055.2; = p.R105C on NM_033046.2) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs778871923, COSV51966539; called by muse, mutect2, varscan2
- RTL3 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV58183782, COSV58184233; called by muse, mutect2, varscan2
- RYR3 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV66809771; called by muse, mutect2, varscan2
- SAFB2 | c.2471dup p.Y825Lfs*9 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | catalogued as rs759920279; called by mutect2, varscan2
- SAMD3 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV63716089; called by muse, mutect2, varscan2
- SATB1 | c.1931A>C p.K644T | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV58673115; called by muse, mutect2, varscan2
- SBF1 | c.4237T>G p.S1413A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV62370700; called by muse, varscan2
- SCAI | c.290T>C p.V97A (on ENST00000336505 / NM_001144877.3; = p.V120A on NM_173690.5) | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60618539; called by muse, mutect2, varscan2
- SCN10A | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV71862753; called by muse, mutect2, varscan2
- SCN5A | c.2343G>A p.W781* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as rs1553701137, COSV61141805; called by muse, mutect2, varscan2
- SCN9A | c.2161T>C p.F721L (on ENST00000303354; = p.F710L on NM_002977.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as COSV57626227; called by muse, mutect2, varscan2
- SCUBE3 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149626853, COSV51460809; called by muse, mutect2, varscan2
- SELE | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV60977973; called by muse, mutect2, varscan2
- SENP7 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); catalogued as COSV58620614; called by muse, mutect2, varscan2
- SEPTIN4 | c.946A>C p.K316Q | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV57899824; called by muse, mutect2, varscan2
- SERPINA11 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.07); catalogued as rs1282454098, COSV58243451; called by muse, mutect2, varscan2
- SERPINB3 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as COSV52193365; called by muse, mutect2, varscan2
- SERPINB5 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs1275909068, COSV66976229; called by muse, mutect2, varscan2
- SFT2D2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 108/213 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV54799763; called by muse, mutect2, varscan2
- SHANK3 | c.4508C>T p.S1503F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53191708; called by muse, mutect2, varscan2
- SHROOM3 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56040270; called by muse, mutect2, varscan2
- SI | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV52299407; called by muse, mutect2, varscan2
- SIGLEC9 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.196); catalogued as COSV99143665; called by muse, mutect2, varscan2
- SIN3B | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56136805; called by muse, mutect2, varscan2
- SIPA1L1 | c.5186+2T>C p.X1729_splice | Splice Site (SNP) | VAF 33/83 reads (40%) | catalogued as COSV62174072; called by muse, mutect2, varscan2
- SLC12A5 | c.794C>T p.A265V (on ENST00000454036 / NM_001134771.2; = p.A242V on NM_020708.5) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV54793156; called by muse, mutect2, varscan2
- SLC15A2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs267599571, COSV55196140; called by muse, mutect2, varscan2
- SLC22A25 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV60599707; called by muse, mutect2, varscan2
- SLC22A9 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV54170657, COSV99655422; called by muse, mutect2, varscan2
- SLC26A8 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62887840; called by muse, mutect2, varscan2
- SLC27A6 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1248096753, COSV52487427; called by muse, mutect2, varscan2
- SLC30A10 | c.1046T>A p.L349Q | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM121954, COSV63076351; called by muse, mutect2, varscan2
- SLC35F4 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1489100806, COSV100333770; called by muse, mutect2, varscan2
- SLC5A3 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 241/671 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62973878; called by muse, mutect2, varscan2
- SLC6A11 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54399611; called by muse, mutect2, varscan2
- SLC6A13 | c.337+1G>A p.X113_splice | Splice Site (SNP) | VAF 24/65 reads (37%) | catalogued as COSV58260782; called by muse, mutect2, varscan2
- SLC9C2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62949862; called by muse, mutect2, varscan2
- SLCO1A2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV56611986; called by muse, mutect2, varscan2
- SLCO1A2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV56598042; called by muse, mutect2, varscan2
- SLCO3A1 | c.1166A>T p.Q389L | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as COSV59238237; called by muse, mutect2, varscan2
- SLIT2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1373460019, COSV56569954, COSV56594632, COSV56596873; called by muse, mutect2
- SLIT2 | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56597453; called by muse, mutect2, varscan2
- SMARCA4 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV60810540; called by muse, mutect2, varscan2
- SMARCC1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs746702299, COSV104392076, COSV54387240; called by muse, mutect2, varscan2
- SMURF1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs774692664, COSV63156412; called by muse, varscan2
- SNAP91 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV52116649; called by muse, mutect2, varscan2
- SNTG2 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57991212; called by muse, mutect2, varscan2
- SORBS2 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV52991586; called by muse, mutect2, varscan2
- SORL1 | c.3250C>T p.R1084C | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52757172; called by muse, mutect2, varscan2
- SOSTDC1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV61050035; called by muse, varscan2
- SPAG17 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs781719346, COSV60455732; called by muse, mutect2, varscan2
- SPANXN5 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as COSV64968799; called by muse, mutect2, varscan2
- SPEF2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532386578, COSV56800906; called by muse, mutect2, varscan2
- SPEM2 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV61604716; called by muse, mutect2, varscan2
- SPIRE2 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV65557857; called by muse, mutect2, varscan2
- SPOCK3 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs181083945; called by muse, mutect2, varscan2
- SPPL2B | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs771423287, COSV71765677; called by muse, mutect2, varscan2
- SPTA1 | c.6386G>A p.R2129K | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs796470277, COSV63749351; called by muse, mutect2, varscan2
- SPTBN4 | c.5233G>A p.E1745K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1462405046, COSV58959327; called by mutect2, varscan2
- SPTLC3 | c.304-1G>A p.X102_splice | Splice Site (SNP) | VAF 49/188 reads (26%) | catalogued as COSV100983318; called by muse, mutect2, varscan2
- SPTLC3 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1568588296, COSV100983319; called by muse, mutect2, varscan2
- SQOR | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.051); catalogued as rs1010238790, COSV52942541, COSV52943725; called by muse, mutect2, varscan2
- SRBD1 | c.2587C>T p.L863F | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as rs1350738831, COSV55406055; called by muse, mutect2, varscan2
- SSX2IP | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60554765; called by mutect2, varscan2
- ST18 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52511294; called by muse, mutect2, varscan2
- ST6GAL2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | PolyPhen possibly damaging (0.566); catalogued as COSV62418298; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.139T>C p.F47L | Missense Mutation (SNP) | VAF 46/139 reads (33%) | PolyPhen benign (0); catalogued as COSV56572798; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.672G>A p.R224= | Splice Region (SNP) | VAF 68/187 reads (36%) | catalogued as COSV59572255; called by muse, mutect2, varscan2
- ST7 | c.1471G>A p.E491K (on ENST00000265437 / NM_021908.3; = p.E468K on NM_018412.4) | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55393655; called by muse, mutect2, varscan2
- ST8SIA3 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | PolyPhen benign (0.011); catalogued as COSV60655522; called by muse, mutect2, varscan2
- STAB2 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs267603273, COSV66336543; called by muse, mutect2, varscan2
- STAT4 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV61832640; called by muse, mutect2, varscan2
- STIL | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV54554167; called by muse, mutect2, varscan2
- STON2 | c.1105A>G p.T369A (on ENST00000649389 / NM_001366849.2; = p.T312A on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV50856228; called by muse, mutect2, varscan2
- STXBP5L | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56537027; called by muse, mutect2, varscan2
- STXBP5L | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56537035; called by muse, mutect2, varscan2
- STYXL2 | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV54810507; called by muse, mutect2, varscan2
- SV2A | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64966039; called by muse, mutect2, varscan2
- SYCP1 | c.2645G>A p.R882K | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); catalogued as rs147186440; called by muse, mutect2, varscan2
- SYT9 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV59625725; called by muse, mutect2, varscan2
- TALDO1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59798740; called by muse, mutect2, varscan2
- TANC1 | c.3590T>A p.L1197Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715501; called by mutect2, varscan2
- TAS1R2 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64747457; called by muse, mutect2, varscan2
- TCF20 | c.3104C>T p.P1035L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1326684759, COSV59496386; called by muse, mutect2, varscan2
- TCF4 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100610758, COSV61907036; called by muse, mutect2, varscan2
- TCHHL1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as COSV64287822; called by muse, mutect2, varscan2
- TCN1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV57254885; called by muse, mutect2, varscan2
- TDRD5 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54251174; called by muse, mutect2, varscan2
- TEAD4 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV63282601; called by muse, mutect2, varscan2
- TECTB | c.563T>G p.V188G | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV65596651; called by muse, mutect2
- TENM3 | c.3647G>A p.R1216K | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV69320615; called by muse, mutect2, varscan2
- TENM3 | c.4973C>T p.A1658V | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV69303852, COSV69320621; called by muse, mutect2, varscan2
- TET2 | c.3205A>G p.T1069A | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV54395076, COSV54404659, COSV54431960; called by muse, mutect2, varscan2
- TEX15 | c.2888G>A p.R963Q (on ENST00000256246; = p.R1346Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as rs776973308, COSV56342158; called by muse, mutect2, varscan2
- THNSL2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV59085071; called by muse, mutect2, varscan2
- THSD7B | c.2231G>A p.S744N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55724590, COSV55741981; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TLN1 | c.5546C>T p.S1849F | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV59211129; called by muse, mutect2, varscan2
- TLR10 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs767103640, COSV58302530; called by muse, mutect2, varscan2
- TLR6 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67935859; called by muse, mutect2, varscan2
- TMC3 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63924758; called by muse, mutect2, varscan2
- TMC5 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.231); catalogued as COSV101196608, COSV66869188; called by muse, mutect2, varscan2
- TMC8 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV59211640; called by muse, mutect2, varscan2
- TMEM196 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs753809570, COSV101337537, COSV68255396; called by muse, mutect2, varscan2
- TMEM225 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs77654932, COSV66693038; called by muse, mutect2, varscan2
- TMEM40 | c.425-1G>A p.X142_splice | Splice Site (SNP) | VAF 18/93 reads (19%) | catalogued as COSV53148926; called by muse, mutect2, varscan2
- TMPRSS3 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52308450; called by muse, mutect2, varscan2
- TMPRSS6 | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100696247; called by muse, mutect2, varscan2
- TMUB2 | c.593C>T p.A198V (on ENST00000538716 / NM_001353177.2; = p.A178V on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV100116360; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59529661; called by muse, mutect2, varscan2
- TNFRSF8 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 29/117 reads (25%) | catalogued as rs868408646, COSV55796948; called by muse, mutect2, varscan2
- TNFSF10 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53844715; called by muse, mutect2, varscan2
- TNN | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV53426617; called by muse, mutect2
- TNN | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV53436704; called by muse, mutect2, varscan2
- TNR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs531733667, COSV54868765; called by muse, mutect2, varscan2
- TPR | c.4022A>C p.H1341P | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV66605408; called by muse, mutect2, varscan2
- TPRG1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV61469175; called by muse, mutect2, varscan2
- TRANK1 | c.4252C>T p.L1418F | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV57165488; called by muse, mutect2, varscan2
- TRBV28 | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs745393218; called by muse, mutect2, varscan2
- TRDV1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.519); catalogued as COSV101153577, COSV66599395; called by muse, mutect2, varscan2
- TRERF1 | c.323G>A p.W108* | Nonsense Mutation (SNP) | VAF 146/301 reads (49%) | catalogued as COSV100549680, COSV61667240, COSV61678544; called by muse, mutect2, varscan2
- TRIM25 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381252; called by muse, mutect2, varscan2
- TRIM9 | c.1171A>G p.R391G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV53625522; called by muse, varscan2
- TRIOBP | c.2717G>A p.W906* | Nonsense Mutation (SNP) | VAF 73/202 reads (36%) | catalogued as COSV60384980; called by muse, mutect2, varscan2
- TRIOBP | c.4120C>T p.P1374S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100731211; called by muse, mutect2, varscan2
- TRIP13 | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV51322442; called by muse, mutect2, varscan2
- TRMT1L | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.278); catalogued as COSV62259414; called by muse, mutect2, varscan2
- TRPC3 | c.2152A>T p.N718Y (on ENST00000379645 / NM_001366479.2; = p.N645Y on NM_003305.2) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.995); catalogued as COSV53381998; called by muse, mutect2, varscan2
- TRPM2 | c.4006C>T p.R1336C | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs143528384; called by mutect2, varscan2
- TSHR | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53332913; called by muse, mutect2, varscan2
- TTC24 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as rs866658135, COSV63998588; called by muse, mutect2, varscan2
- TTN | c.24358C>T p.P8120S (on ENST00000591111; = p.P7193S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | PolyPhen benign (0); catalogued as COSV60375532; called by muse, mutect2, varscan2
- TTN | c.14087T>C p.V4696A (on ENST00000591111; = p.V3769A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | PolyPhen benign (0.254); catalogued as COSV60375551; called by muse, mutect2, varscan2
- TTN | c.6907G>A p.D2303N (on ENST00000591111; = p.D2257N on NM_003319.4) | Missense Mutation (SNP) | VAF 34/135 reads (25%) | PolyPhen benign (0.003); catalogued as rs779125886, COSV59978249, COSV60274688; called by muse, mutect2, varscan2
- TTN | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 44/135 reads (33%) | PolyPhen benign (0.01); catalogued as rs1029708061, COSV60375609; called by muse, mutect2, varscan2
- TUBGCP4 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53017633, COSV53020147; called by muse, varscan2
- TXNDC16 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as rs372133582; called by muse, mutect2, varscan2
- UBN1 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52173495; called by muse, mutect2, varscan2
- UGT2A1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54146972; called by muse, mutect2, varscan2
- UNC13A | c.3484G>A p.D1162N | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV53211861; called by muse, mutect2, varscan2
- UNC5D | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV54839721; called by muse, mutect2, varscan2
- UNC79 | c.859C>T p.P287S (on ENST00000393151 / NM_001346218.2; = p.P110S on NM_020818.5) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV56413401; called by muse, mutect2, varscan2
- USH2A | c.8734C>T p.P2912S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100244282; called by muse, mutect2, varscan2
522 further variants in this file (60 protein-altering or splice-affecting, 421 silent, 41 other) are not listed here.
